Somatic mutation profile of tumor specimen TARGET-15-PARWPU-09A.1 (aliquot TARGET-15-PARWPU-09A.1-01D) from TARGET case TARGET-15-PARWPU, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,129 days).
Specimen TARGET-15-PARWPU-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 475386ca-3d4a-496a-9e9e-5011daa2dc8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-PARWPU-14A (Bone Marrow Normal), aliquot TARGET-15-PARWPU-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/709116cf-327c-4269-8ce9-73c61d98750f

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FEM1A | c.1085C>A p.A362E | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV54163778; called by muse, mutect2
- SEMA5B | c.2138G>T p.C713F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- SPATA20 | c.1668C>A p.Y556* (on ENST00000356488 / NM_001258372.1; = p.Y572* on NM_022827.4) | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- UAP1 | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2
- HES1 | c.456C>A p.A152= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- SLC4A9 | c.2208C>A p.I736= (on ENST00000507527 / NM_001258428.2; = p.I712= on NM_031467.3) | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- CCL16 | c.-6G>T | 5'UTR (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- PLD1 | c.-32+17635G>T | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
